Somatic mutation profile of tumor specimen TCGA-D1-A160-01A (aliquot TCGA-D1-A160-01A-11D-A122-09) from TCGA case TCGA-D1-A160, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.3 years (25,673 days).
Specimen TCGA-D1-A160-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6333c7ca-b88a-4dfc-a466-53916bbc5bda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A160-10A (Blood Derived Normal), aliquot TCGA-D1-A160-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1abe46c-34e2-4b88-8629-e30880f30643

The open-access MAF lists 613 somatic variants for this specimen: 482 protein-altering or splice-affecting, 116 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 321, Silent 116, Frame Shift Del 95, Nonsense Mutation 24, Frame Shift Ins 23, Splice Site 10, Intron 8, Splice Region 5, In Frame Del 4, 3'UTR 3, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 42/273 reads (15%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CAPN3 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141656719, CM950194; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHD7 | c.2090del p.K697Sfs*14 | Frame Shift Del (DEL) | VAF 86/282 reads (30%) | catalogued as rs1563595385; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GALT | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); catalogued as rs111033735, CM950551, COSV66593644; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel
- KMT2D | c.5104C>T p.R1702* | Nonsense Mutation (SNP) | VAF 38/99 reads (38%) | catalogued as rs886043414, COSV56407907; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 152/382 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 116/289 reads (40%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.437T>A p.L146* | Nonsense Mutation (SNP) | VAF 97/267 reads (36%) | hotspot (GDC flag); catalogued as rs786204933, CD104225, COSV64290532, COSV64291883, COSV64294541; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2801dup p.N934Kfs*10 | Frame Shift Ins (INS) | VAF 148/396 reads (37%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- AACS | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs376023356; called by muse, mutect2, varscan2
- ABCA13 | c.11600G>T p.R3867I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV71295715; called by muse, mutect2, varscan2
- ACOT12 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 73/189 reads (39%) | catalogued as rs776472585, COSV56897832; called by muse, mutect2, varscan2
- ACSL4 | c.1463T>C p.V488A (on ENST00000340800 / NM_022977.2; = p.V447A on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 183/491 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61616100; called by muse, mutect2, varscan2
- ACTA1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1553255312, CM095327, COSV64204229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS1 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV53173967; called by muse, mutect2, varscan2
- ADAMTS17 | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51495652; called by muse, mutect2, varscan2
- ADGRG2 | c.305G>A p.G102D (on ENST00000379869 / NM_001079858.3; = p.G99D on NM_005756.4) | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV61341732; called by muse, mutect2, varscan2
- ADPRHL1 | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62911065; called by muse, mutect2, varscan2
- AEBP2 | c.800A>G p.Q267R | Missense Mutation (SNP) | VAF 159/505 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.348); catalogued as COSV56866768; called by muse, mutect2, varscan2
- AGAP2 | c.809A>G p.K270R | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV57732737; called by muse, mutect2, varscan2
- AK9 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV53424563; called by muse, mutect2, varscan2
- AKAP9 | c.6845T>A p.M2282K (on ENST00000359028; = p.M2258K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/289 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV62359248; called by muse, mutect2, varscan2
- AKT1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.315); catalogued as COSV62576536; called by muse, mutect2, varscan2
- ALDH1A1 | c.10T>G p.S4A | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.01); catalogued as COSV52794811; called by muse, mutect2, varscan2
- ALDH1L2 | c.2626G>T p.A876S | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51560484; called by muse, mutect2, varscan2
- ALKBH4 | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV52962461; called by muse, mutect2, varscan2
- ALMS1 | c.7703G>A p.C2568Y | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs1259003551, COSV100041813; called by muse, mutect2
- ANGPTL1 | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 94/435 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.735); catalogued as COSV52368448; called by muse, mutect2, varscan2
- ANGPTL2 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52234246; called by muse, mutect2, varscan2
- ANKH | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV52487383; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 70/177 reads (40%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKIB1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as COSV56066700; called by muse, mutect2, varscan2
- ANPEP | c.635T>C p.M212T | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55595739; called by muse, mutect2, varscan2
- APOBR | c.1225G>T p.E409* (on ENST00000431282; = p.E418* on NM_018690.4) | Nonsense Mutation (SNP) | VAF 47/128 reads (37%) | catalogued as COSV60494573; called by muse, mutect2, varscan2
- APOL6 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV68749810; called by muse, mutect2, varscan2
- APP | c.2054A>G p.H685R | Missense Mutation (SNP) | VAF 164/401 reads (41%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.984); catalogued as rs769722329, COSV61005803; called by muse, mutect2, varscan2
- AR | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65964685; called by muse, mutect2, varscan2
- ARFGEF3 | c.4391C>T p.A1464V | Missense Mutation (SNP) | VAF 124/297 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1287152885, COSV52472546; called by muse, mutect2, varscan2
- ARFGEF3 | c.5408C>G p.A1803G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV99292896; called by muse, mutect2
- ARHGAP18 | c.967dup p.C323Lfs*32 | Frame Shift Ins (INS) | VAF 95/320 reads (30%) | catalogued as rs1292136331; called by mutect2, pindel, varscan2
- ARHGAP21 | c.1894C>T p.H632Y | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57611924; called by muse, mutect2, varscan2
- ARHGAP22 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as rs1467062638; called by muse, mutect2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | catalogued as rs781483073; called by mutect2, pindel, varscan2
- ARID1A | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100251965, COSV61372105; called by muse, mutect2, varscan2
- ARMCX1 | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV65705639; called by muse, mutect2, varscan2
- ARMCX3 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV57871869; called by muse, mutect2, varscan2
- ASAP2 | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs553146291, COSV55632933, COSV99856882; called by muse, mutect2, varscan2
- ATP2B3 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV54863715; called by muse, mutect2, varscan2
- ATP2B4 | c.261dup p.K88Qfs*40 | Frame Shift Ins (INS) | VAF 60/327 reads (18%) | catalogued as rs769726180; called by mutect2, varscan2
- ATP2B4 | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as COSV58182719; called by muse, mutect2, varscan2
- ATXN7 | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as rs772199550, COSV55757407; called by muse, mutect2, varscan2
- ATXN7L2 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV63993030; called by muse, mutect2, varscan2
- AXDND1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 90/501 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.286); catalogued as rs200125774, COSV62639986; called by muse, mutect2, varscan2
- AXIN2 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61061638; called by muse, mutect2, varscan2
- B4GALT2 | c.21del p.T8Rfs*102 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs759490732, COSV99356264; called by mutect2, pindel
- B4GALT2 | c.738C>T p.F246= | Splice Region (SNP) | VAF 11/25 reads (44%) | catalogued as COSV58846478; called by muse, mutect2, varscan2
- BAG2 | c.371T>G p.F124C | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.67); catalogued as COSV58099664; called by muse, mutect2, varscan2
- BAIAP3 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs375777655, COSV50103683; called by muse, mutect2, varscan2
- BBS9 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 136/415 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV54190213; called by muse, varscan2
- BCKDK | c.685A>T p.K229* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as COSV54894257; called by muse, mutect2, varscan2
- BIRC6 | c.10258T>C p.F3420L | Missense Mutation (SNP) | VAF 123/358 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.076); catalogued as COSV70195453, COSV70207099; called by muse, varscan2
- BLVRB | c.244+2T>C p.X82_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV54570641; called by muse, mutect2, varscan2
- BOLA3 | c.182C>A p.A61E | Missense Mutation (SNP) | VAF 135/371 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs759777200, COSV54877647; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 62/188 reads (33%) | catalogued as COSV56263190; called by mutect2, varscan2
- BRINP2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771272662, COSV100838021, COSV64180814; called by muse, mutect2, varscan2
- BTN2A2 | c.1187T>C p.V396A | Missense Mutation (SNP) | VAF 118/379 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs760200685, COSV61858880; called by muse, mutect2, varscan2
- C16orf46 | c.793del p.R265Efs*27 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs1336054942; called by mutect2, varscan2
- C1QTNF9B | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 86/406 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65944694; called by muse, mutect2, varscan2
- C1orf116 | c.1719dup p.C574Lfs*14 | Frame Shift Ins (INS) | VAF 24/157 reads (15%) | catalogued as rs780657010; called by mutect2, varscan2
- CA3 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53411632; called by muse, mutect2, varscan2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/152 reads (34%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CBX3 | c.42del p.K14Nfs*23 | Frame Shift Del (DEL) | VAF 133/427 reads (31%) | catalogued as COSV61761904; called by mutect2, pindel, varscan2
- CC2D2B | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 103/317 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369417630; called by muse, mutect2, varscan2
- CCN4 | c.269C>G p.A90G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV51536460; called by muse, mutect2, varscan2
- CD226 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54616674, COSV99711181; called by muse, mutect2, varscan2
- CD300LB | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV58725738, COSV58726746; called by muse, mutect2, varscan2
- CDCP1 | c.1816A>G p.M606V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.019); catalogued as rs542306283, COSV56108513; called by mutect2, varscan2
- CDH18 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56966772; called by muse, mutect2, varscan2
- CDH23 | c.6405G>T p.E2135D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56493914, COSV99820131; called by muse, mutect2, varscan2
- CELF5 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV53014138; called by muse, mutect2, varscan2
- CEP104 | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV65520052; called by muse, mutect2, varscan2
- CEP126 | c.2018T>C p.I673T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV54831632; called by muse, mutect2, varscan2
- CEP152 | c.4967G>A p.C1656Y (on ENST00000380950 / NM_001194998.2; = p.C1600Y on NM_014985.4) | Missense Mutation (SNP) | VAF 154/369 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57865694; called by muse, mutect2, varscan2
- CFH | c.3056C>T p.A1019V | Missense Mutation (SNP) | VAF 100/433 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.571); catalogued as COSV66414381; called by muse, mutect2, varscan2
- CHD6 | c.7480G>T p.G2494W | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64695229; called by muse, mutect2, varscan2
- CHD6 | c.4251A>T p.E1417D | Missense Mutation (SNP) | VAF 101/259 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV64695234; called by muse, mutect2, varscan2
- CHERP | c.1849dup p.H617Pfs*22 | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | catalogued as rs757443115; called by mutect2, varscan2
- CKAP2 | c.736A>G p.T246A (on ENST00000378037 / NM_001098525.2; = p.T245A on NM_018204.5) | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs1167730835, COSV51625074; called by muse, mutect2, varscan2
- CKAP4 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 59/180 reads (33%) | catalogued as COSV65173338; called by muse, mutect2, varscan2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 54/164 reads (33%) | catalogued as rs754415052; called by mutect2, varscan2
- CLASP2 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV56295613; called by muse, varscan2
- CLEC18B | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60579104; called by muse, mutect2, varscan2
- CMYA5 | c.12013C>T p.R4005C | Missense Mutation (SNP) | VAF 135/347 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs780702412, COSV69746351; called by muse, mutect2, varscan2
- CNPY2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 126/337 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as rs886916815, COSV56264277; called by muse, mutect2, varscan2
- CNTD1 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs766100218, COSV55911139; called by muse, mutect2, varscan2
- CNTN6 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776905020, COSV63192171; called by muse, mutect2, varscan2
- CNTNAP3 | c.3370A>C p.K1124Q | Missense Mutation (SNP) | VAF 173/509 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as COSV52676873; called by muse, mutect2, varscan2
- CNTNAP5 | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1238957717, COSV70515547; called by muse, varscan2
- COL1A2 | c.2069C>A p.T690K | Missense Mutation (SNP) | VAF 198/498 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV51960891, COSV51967364; called by muse, mutect2, varscan2
- COQ8A | c.1805del p.P602Hfs*22 | Frame Shift Del (DEL) | VAF 35/205 reads (17%) | catalogued as rs768233728; called by mutect2, pindel, varscan2
- CR2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 76/385 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as rs759786703, COSV65506396; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRISP3 | c.441G>A p.W147* (on ENST00000371159 / NM_001368123.1; = p.W129* on NM_006061.4) | Nonsense Mutation (SNP) | VAF 107/274 reads (39%) | catalogued as COSV53823759; called by muse, mutect2, varscan2
- CRYBA4 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61323086; called by muse, mutect2, varscan2
- CSMD2 | c.6947A>G p.D2316G | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1557579687, COSV99587977; called by muse, mutect2
- CTPS1 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV65454524; called by muse, mutect2, varscan2
- CUX1 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.277); catalogued as COSV52918353; called by muse, mutect2, varscan2
- CWH43 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 160/447 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56938506, COSV56944685; called by muse, mutect2, varscan2
- CYTH2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); catalogued as rs368161948; called by muse, mutect2, varscan2
- DDX4 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768783395, COSV61755195, COSV61757655; called by muse, mutect2, varscan2
- DENND5B | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 82/390 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60909199; called by muse, mutect2, varscan2
- DESI2 | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV55643470; called by muse, varscan2
- DGKH | c.1796T>A p.L599H | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV54943366; called by muse, mutect2, varscan2
- DHX15 | c.2070A>C p.R690S | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61029552; called by muse, mutect2, varscan2
- DIP2C | c.3785C>T p.T1262I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV55181875; called by muse, mutect2, varscan2
- DISC1 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 78/413 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54420378; called by muse, mutect2, varscan2
- DLG2 | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 54/135 reads (40%) | catalogued as COSV54624971; called by muse, mutect2, varscan2
- DMC1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV53261254; called by muse, mutect2, varscan2
- DMD | c.5969C>A p.P1990H | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.77); catalogued as COSV63798386; called by muse, mutect2, varscan2
- DNAAF1 | c.573C>A p.L191= | Splice Region (SNP) | VAF 37/120 reads (31%) | catalogued as COSV100533851, COSV57579248; called by muse, mutect2, varscan2
- DNAAF4 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 188/484 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58252013; called by muse, mutect2, varscan2
- DNAH10 | c.9091G>A p.V3031I (on ENST00000409039; = p.V2970I on NM_207437.3) | Missense Mutation (SNP) | VAF 117/294 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV69003775; called by muse, mutect2, varscan2
- DNAI2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.169); catalogued as COSV56762993; called by muse, varscan2
- DOCK11 | c.4877C>T p.A1626V | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV52248809; called by muse, mutect2, varscan2
- DSCAM | c.3508C>T p.R1170C | Missense Mutation (SNP) | VAF 93/181 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs770700594, COSV68030486; called by muse, mutect2, varscan2
- DSP | c.3806G>A p.R1269Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.199); catalogued as rs876657795, COSV65796626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSPP | c.3508G>A p.D1170N | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.428); catalogued as rs1314749555, COSV56817372; called by muse, mutect2, varscan2
- DTX3L | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1409600072, COSV56145865; called by muse, mutect2, varscan2
- ECE1 | c.616-1G>T p.X206_splice | Splice Site (SNP) | VAF 40/102 reads (39%) | catalogued as COSV51671380; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100668514; called by muse, mutect2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 123/354 reads (35%) | catalogued as rs770453803; called by mutect2, varscan2
- EP300 | c.1529-2A>G p.X510_splice | Splice Site (SNP) | VAF 211/565 reads (37%) | catalogued as COSV54347001; called by muse, mutect2, varscan2
- EPPK1 | c.1612G>A p.V538M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs782111699, COSV73262457; called by muse, mutect2, varscan2
- EPS15L1 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 176/481 reads (37%) | catalogued as COSV50176944; called by muse, mutect2, varscan2
- ERCC4 | c.2495C>T p.T832I | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as COSV61314185; called by muse, mutect2, varscan2
- ERVW-1 | c.1563G>T p.E521D | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as rs1286777928, COSV101423822; called by muse, mutect2
- EXOSC10 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 65/550 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as COSV58668452; called by muse, mutect2, varscan2
- F8 | c.2915T>C p.M972T | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV64279436; called by muse, mutect2, varscan2
- FAM117A | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV53634286; called by muse, mutect2, varscan2
- FAM227B | c.169del p.I57* | Frame Shift Del (DEL) | VAF 52/169 reads (31%) | catalogued as COSV100174843, COSV100175622; called by mutect2, pindel, varscan2
- FANCD2 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 160/423 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752621186, COSV55047710; called by muse, mutect2, varscan2
- FAT1 | c.7833A>C p.K2611N | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV71676248; called by muse, mutect2, varscan2
- FBXL12 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs751207779, COSV56115096; called by muse, mutect2, varscan2
- FBXW7 | c.386A>C p.D129A | Missense Mutation (SNP) | VAF 154/452 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV55965811; called by muse, mutect2, varscan2
- FER1L5 | c.5683G>A p.A1895T (on ENST00000623019; = p.A1859T on NM_001293083.2) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs749061451, COSV53844378; called by muse, mutect2, varscan2
- FFAR4 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 152/457 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.285); catalogued as COSV65160880; called by muse, mutect2, varscan2
- FGF13 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 23/503 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263896; called by muse, mutect2
- FHDC1 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.087); catalogued as rs775250201, COSV52603825; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs769482947; called by mutect2, varscan2
- FLYWCH1 | c.1820del p.G607Afs*38 (on ENST00000253928 / NM_001308068.2; = p.G606Afs*38 on NM_020912.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as COSV99559156; called by mutect2, pindel, varscan2
- FMNL3 | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53308561; called by muse, mutect2, varscan2
- FPR2 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60674670; called by muse, mutect2, varscan2
- GALNT15 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV60220224; called by muse, mutect2, varscan2
- GFOD1 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64955500; called by muse, mutect2
- GFPT2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 152/500 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53813234; called by muse, mutect2, varscan2
- GLI3 | c.3937C>T p.Q1313* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV67895099, COSV67895651; called by muse, mutect2, varscan2
- GNPTAB | c.1037T>C p.I346T | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV68450026; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 142/374 reads (38%) | catalogued as rs370114090; called by mutect2, varscan2
- GPHN | c.2110C>T p.R704C (on ENST00000315266 / NM_001377519.1; = p.R737C on NM_020806.5) | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1484644467, COSV59480697; called by muse, mutect2, varscan2
- GPRIN2 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.805); catalogued as rs1282346133, COSV65400755; called by muse, mutect2
- GRAMD1B | c.476T>C p.M159T | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs1565436059, COSV100454117; called by muse, mutect2
- GRB10 | c.1265C>T p.T422M (on ENST00000398812; = p.T376M on NM_001001549.3) | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs932870989, COSV60010417; called by muse, mutect2, varscan2
- GRIA2 | c.2642T>C p.V881A | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV99643727; called by muse, mutect2
- GRPR | c.1000A>C p.N334H | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV66670372; called by muse, mutect2, varscan2
- GRXCR2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 152/443 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0.036); catalogued as COSV65062026; called by muse, mutect2, varscan2
- GTF3C3 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); catalogued as COSV55832350, COSV55834936; called by muse, mutect2, varscan2
- GTPBP10 | c.926dup p.N309Kfs*37 | Frame Shift Ins (INS) | VAF 128/346 reads (37%) | catalogued as rs745885335; called by mutect2, varscan2
- HAUS5 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs750360328, COSV52549096, COSV52550235; called by muse, mutect2, varscan2
- HCN1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 142/386 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV57540589; called by muse, mutect2, varscan2
- HDAC8 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 20/545 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs782717694, COSV65265797; called by muse, mutect2
- HDX | c.1192T>C p.S398P | Missense Mutation (SNP) | VAF 61/469 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.795); catalogued as COSV99946980; called by muse, mutect2, varscan2
- HELZ2 | c.3161C>T p.A1054V (on ENST00000467148 / NM_001037335.2; = p.A485V on NM_033405.3) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1483722686, COSV64410616; called by muse, mutect2, varscan2
- HLX | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV65045799; called by muse, mutect2, varscan2
- HNRNPM | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 132/346 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57694939; called by muse, mutect2, varscan2
- HSPA6 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV59063048; called by muse, mutect2, varscan2
- HTR1A | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60503303; called by muse, mutect2, varscan2
- HYDIN | c.13958A>G p.N4653S | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66642804; called by muse, varscan2
- ICE2 | c.931A>T p.I311L | Missense Mutation (SNP) | VAF 164/419 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV55034400; called by muse, mutect2, varscan2
- IFNA8 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV66505152; called by muse, mutect2, varscan2
- IGSF9 | c.1915del p.V639Yfs*114 (on ENST00000368094 / NM_001135050.2; = p.V623Yfs*114 on NM_020789.4) | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as COSV63641012; called by mutect2, pindel, varscan2
- IL37 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 100/261 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99636086; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INPPL1 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV53359900; called by muse, mutect2, varscan2
- INTS10 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 119/343 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV67605197; called by muse, mutect2, varscan2
- INTS12 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 166/483 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV60863804; called by muse, mutect2, varscan2
- INVS | c.289A>G p.M97V | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as rs1298161054, COSV52451351; called by muse, mutect2, varscan2
- IPO9 | c.1219C>T p.L407= | Splice Region (SNP) | VAF 113/562 reads (20%) | catalogued as rs1327977789, COSV64236627; called by muse, mutect2, varscan2
- IPO9 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 89/393 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as rs955357935, COSV64236631; called by muse, mutect2, varscan2
- IRAK2 | c.1538G>A p.S513N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV56536344; called by muse, mutect2, varscan2
- JADE1 | c.2230C>A p.P744T | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.286); catalogued as COSV99885561; called by muse, mutect2, varscan2
- KANSL1 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV52274924; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 29/109 reads (27%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as COSV58583583, COSV58589056; called by mutect2, pindel
- KCNE2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs141423405, CM064063; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- KCNG2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs919202700, COSV60266951; called by muse, mutect2
- KCNQ3 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV66483583; called by muse, mutect2, varscan2
- KCTD11 | c.470A>G p.Q157R (on ENST00000333751 / NM_001363642.1; = p.Q118R on NM_001002914.2) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1324308461, COSV99341520; called by muse, mutect2
- KIAA1109 | c.358+1G>A p.X120_splice | Splice Site (SNP) | VAF 27/543 reads (5%) | catalogued as COSV99151074; called by muse, mutect2
- KIAA1549 | c.5432G>A p.R1811Q | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1357171842, COSV54331172; called by muse, mutect2, varscan2
- KIAA2026 | c.6071G>A p.C2024Y | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV67358160; called by muse, mutect2, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 45/104 reads (43%) | catalogued as rs749990720; called by mutect2, varscan2
- KIFC1 | c.1286A>G p.Q429R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.872); catalogued as COSV65737968; called by muse, mutect2, varscan2
- KITLG | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 109/287 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV57204360; called by muse, mutect2, varscan2
- KRT28 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs768445733, COSV60686608; called by muse, mutect2, varscan2
- KRT75 | c.1107A>C p.E369D | Missense Mutation (SNP) | VAF 143/414 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV52875551; called by muse, mutect2, varscan2
- LARGE1 | c.894G>A p.G298= | Splice Region (SNP) | VAF 38/126 reads (30%) | catalogued as COSV61673606; called by muse, mutect2, varscan2
- LAS1L | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 201/586 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV56709294; called by muse, mutect2, varscan2
- LECT2 | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.082); catalogued as COSV50847740; called by muse, mutect2, varscan2
- LGALS3BP | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.084); catalogued as rs760731529, COSV53166269; called by muse, mutect2, varscan2
- LILRB1 | c.332A>G p.Q111R (on ENST00000427581; = p.Q75R on NM_006669.6) | Missense Mutation (SNP) | VAF 132/554 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV100207109; called by muse, mutect2, varscan2
- LIN54 | c.1744A>G p.K582E | Missense Mutation (SNP) | VAF 149/393 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61203113; called by muse, mutect2, varscan2
- LNX2 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 97/271 reads (36%) | catalogued as rs754978843, COSV60336695; called by muse, mutect2, varscan2
- LRSAM1 | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100031330; called by muse, mutect2
- LTB4R2 | c.982C>G p.P328A (on ENST00000528054; = p.P297A on NM_019839.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV51868385; called by muse, mutect2, varscan2
- LTN1 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 116/338 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs772950564, COSV63735512; called by muse, mutect2, varscan2
- LYN | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101319593; called by muse, mutect2
- LYPLA2 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65721129; called by muse, mutect2, varscan2
- MAST1 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52256354; called by muse, mutect2, varscan2
- MASTL | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 124/324 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374260260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MED1 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 50/508 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.186); catalogued as COSV56129064; called by muse, mutect2
- MED12L | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV56400135; called by muse, mutect2, varscan2
- MED25 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV57207799; called by muse, mutect2, varscan2
- MFSD14A | c.1289C>A p.P430H | Missense Mutation (SNP) | VAF 120/335 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54930713; called by muse, mutect2, varscan2
- MGAT4C | c.814T>G p.L272V | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59838705; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MLNR | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs1372559333, COSV54534698; called by muse, mutect2, varscan2
- MPG | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as rs560374683, COSV54739759; called by muse, mutect2, varscan2
- MTUS2 | c.3274C>T p.Q1092* (on ENST00000612955 / NM_001366650.1; = p.Q71* on NM_015233.6) | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV60158748; called by muse, mutect2, varscan2
- MYCN | c.1157A>G p.H386R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284212565, COSV55259245; called by muse, mutect2
- MYH10 | c.2930A>C p.E977A | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV52613029; called by muse, mutect2, varscan2
- MYH7B | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1398401210, COSV52685131; called by muse, mutect2, varscan2
- MYMK | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV60601766; called by muse, mutect2, varscan2
- MYO16 | c.172T>C p.F58L | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV51821587; called by muse, mutect2, varscan2
- MYO18A | c.2863A>G p.T955A | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62874624; called by muse, mutect2
- MYO3A | c.4403T>C p.I1468T | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV56352119; called by muse, mutect2, varscan2
- MYO6 | c.1133T>C p.L378S | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562251123, COSV64121824; called by muse, mutect2, varscan2
- NCF2 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 163/752 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV62316930; called by muse, mutect2, varscan2
- NCOA6 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV62868582; called by muse, mutect2, varscan2
- NEK6 | c.118T>C p.C40R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.07); catalogued as COSV57221820; called by muse, mutect2, varscan2
- NFKB2 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs1425541702, COSV50065894; called by muse, mutect2, varscan2
- NHLRC2 | c.2021T>C p.L674S | Missense Mutation (SNP) | VAF 116/295 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV65176308; called by muse, mutect2, varscan2
- NPHP4 | c.463T>C p.Y155H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.189); catalogued as COSV65398526; called by muse, varscan2
- NPM2 | c.539dup p.L181Afs*13 | Frame Shift Ins (INS) | VAF 90/289 reads (31%) | catalogued as rs770540772; called by mutect2, varscan2
- NPTX2 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs371914516; called by muse, mutect2, varscan2
- NR1I3 | c.970C>T p.R324W (on ENST00000367982 / NM_001077480.3; = p.R320W on NM_005122.5) | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369817002, COSV100915553; called by muse, mutect2, varscan2
- NUP210L | c.1501_1503del p.S501del | In Frame Del (DEL) | VAF 60/326 reads (18%) | catalogued as rs1557988637; called by pindel, varscan2
- OGDH | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56058076; called by muse, mutect2, varscan2
- OR9G4 | c.353T>C p.M118T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57250067; called by muse, mutect2, varscan2
- P2RX6 | c.186del p.G63Afs*39 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs759868874, COSV99488575; called by mutect2, pindel, varscan2
- P3H3 | c.1585A>G p.S529G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs782642552, COSV51836874; called by muse, mutect2, varscan2
- PADI1 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs367912075, COSV64933888; called by muse, mutect2, varscan2
- PCDHA1 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV65375149; called by muse, mutect2, varscan2
- PCDHA3 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as COSV65365639; called by muse, mutect2
- PCK2 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1298557532, COSV53751082; called by muse, mutect2, varscan2
- PCSK2 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs752788983, COSV52744812; called by muse, mutect2, varscan2
- PDCD11 | c.5572G>A p.A1858T | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53298179; called by muse, mutect2
- PDE11A | c.1958C>T p.T653I | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53711088; called by muse, mutect2, varscan2
- PDE1C | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 36/583 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100371867; called by muse, mutect2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | catalogued as rs747131399; called by mutect2, varscan2
- PFKFB3 | c.1033T>C p.Y345H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | PolyPhen benign (0.414); catalogued as COSV57993898; called by muse, mutect2, varscan2
- PGLYRP3 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99319416; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF21A | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as rs780150629, COSV99138264; called by muse, mutect2
- PIGQ | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs149108761, COSV99215901; called by muse, mutect2
- PIGR | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV62905210; called by muse, mutect2, varscan2
- PIK3CG | c.723del p.G242Afs*17 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as COSV63248912; called by mutect2, pindel, varscan2
- PLCG1 | c.2932C>T p.R978W | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs755375534, COSV54818173; called by muse, mutect2, varscan2
- PLEKHA6 | c.2672A>G p.E891G | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55341106; called by muse, mutect2, varscan2
- PLXNA2 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs1022090935, COSV65442785; called by muse, mutect2, varscan2
- PLXNB1 | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1159093912, COSV99602568; called by muse, varscan2
- PNKP | c.1204T>G p.W402G | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55591016; called by muse, mutect2, varscan2
- POLD1 | c.347del p.P116Hfs*53 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as COSV101486926; called by mutect2, pindel, varscan2
- POM121 | c.3526G>A p.G1176R (on ENST00000434423; = p.G911R on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1554502518, COSV57524659; called by muse, mutect2, varscan2
- POTEE | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 46/166 reads (28%) | catalogued as rs772047281; called by mutect2, varscan2
- PPP2R3B | c.638A>G p.D213G | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV66814580; called by muse, mutect2, varscan2
- PQBP1 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.435); catalogued as COSV54432157, COSV99504424; called by muse, mutect2
- PRELP | c.1054C>A p.L352M | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58117783; called by muse, mutect2, varscan2
- PROP1 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100383660; called by muse, mutect2
- PRPF3 | c.1168T>G p.W390G | Missense Mutation (SNP) | VAF 86/445 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61396628; called by muse, mutect2, varscan2
- PRRC1 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV56992516; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 64/192 reads (33%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PTPN3 | c.588-2A>T p.X196_splice | Splice Site (SNP) | VAF 10/206 reads (5%) | catalogued as COSV99355555; called by muse, mutect2
- RAB18 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 138/423 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63614076; called by muse, mutect2, varscan2
- RAB41 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 120/273 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as COSV52105490; called by muse, mutect2, varscan2
- RABGEF1 | c.1119C>T p.C373= (on ENST00000439720 / NM_001287061.2; = p.C360= on NM_014504.3 and 29 other RefSeq transcripts) | Splice Region (SNP) | VAF 94/249 reads (38%) | catalogued as COSV53165600; called by muse, mutect2, varscan2
- RAE1 | c.749+1G>T p.X250_splice | Splice Site (SNP) | VAF 161/412 reads (39%) | catalogued as COSV64799108; called by muse, mutect2, varscan2
- RAI1 | c.3992C>T p.A1331V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55400053; called by muse, mutect2, varscan2
- RBL2 | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 44/128 reads (34%) | catalogued as COSV50890522; called by muse, mutect2, varscan2
- RBM47 | c.249C>A p.Y83* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV55933120; called by muse, mutect2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 142/410 reads (35%) | catalogued as COSV56484832; called by mutect2, varscan2
- RDH8 | c.857C>T p.T286M (on ENST00000651512; = p.T266M on NM_015725.4) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745469395, COSV50674145; called by muse, mutect2, varscan2
- RESF1 | c.4684A>C p.S1562R | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV57026292; called by muse, mutect2, varscan2
- REST | c.3241C>T p.R1081C | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs745688107, COSV58360056; called by muse, mutect2, varscan2
- RET | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs774092678, COSV60701999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REV3L | c.3242C>G p.S1081* | Nonsense Mutation (SNP) | VAF 135/417 reads (32%) | catalogued as COSV104415785, COSV62619186, COSV62624248; called by muse, mutect2, varscan2
- RFC1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 125/382 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.035); catalogued as COSV62901383; called by muse, mutect2, varscan2
- RGS22 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 168/475 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62668679; called by muse, mutect2, varscan2
- RHOG | c.109T>C p.F37L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV53467923; called by muse, mutect2, varscan2
- RMND5B | c.18C>A p.C6* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV57746555; called by muse, mutect2, varscan2
- RNF20 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs201929039; called by muse, mutect2, varscan2
- RNF41 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 207/482 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61505292; called by muse, mutect2, varscan2
- ROBO3 | c.2425T>C p.W809R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs991359504, COSV67303288; called by muse, mutect2, varscan2
- ROBO3 | c.3928C>A p.L1310M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as rs1297108111; called by muse, mutect2
- ROBO4 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV60628501; called by muse, mutect2, varscan2
- RPS3 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV53705639; called by muse, mutect2, varscan2
- RPUSD4 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.304); catalogued as COSV53600436; called by muse, mutect2, varscan2
- RUBCN | c.1639C>A p.R547S | Missense Mutation (SNP) | VAF 103/276 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56375503; called by mutect2, varscan2
- RUSC2 | c.2927G>A p.C976Y | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63430841; called by muse, mutect2, varscan2
- RYR2 | c.2116T>C p.Y706H | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63718936; called by muse, mutect2, varscan2
- SAP130 | c.2607G>T p.K869N | Missense Mutation (SNP) | VAF 135/396 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.415); catalogued as COSV52103834; called by muse, mutect2, varscan2
- SASS6 | c.1573T>G p.C525G | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV54930727; called by muse, mutect2, varscan2
- SAXO1 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 14/482 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101000131; called by muse, mutect2
- SBK1 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV59399311; called by muse, mutect2, varscan2
- SCARA5 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs760986821, COSV57281942; called by muse, mutect2, varscan2
- SDF2L1 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1378265009, COSV50708121; called by muse, mutect2, varscan2
- SEC14L5 | c.1863del p.S622Afs*14 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs764657044; called by mutect2, pindel, varscan2
- SECISBP2 | c.76A>G p.R26G | Missense Mutation (SNP) | VAF 117/360 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV58686954; called by muse, mutect2, varscan2
- SELL | c.805G>T p.V269L (on ENST00000650983; = p.V256L on NM_000655.5) | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs908811745, COSV52555389; called by muse, mutect2, varscan2
- SEPTIN1 | c.1176G>T p.E392D (on ENST00000321367; = p.E345D on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.496); catalogued as COSV58444105; called by muse, mutect2, varscan2
- SERPINB8 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 126/339 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV54640817; called by muse, mutect2, varscan2
- SERPINI2 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV52989350; called by muse, mutect2, varscan2
- SETX | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 69/411 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56396139; called by muse, mutect2, varscan2
- SF3B2 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV59430472; called by muse, mutect2, varscan2
- SF3B4 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); catalogued as COSV54967150; called by muse, mutect2, varscan2
- SFMBT2 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62817773; called by muse, mutect2, varscan2
- SHPRH | c.2989dup p.S997Kfs*19 (on ENST00000275233 / NM_001042683.3; = p.S997Kfs*3 on NM_173082.3) | Frame Shift Ins (INS) | VAF 10/39 reads (26%) | catalogued as rs1318229617; called by mutect2, pindel
- SIGIRR | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369156823, COSV58990436; called by muse, mutect2, varscan2
- SIGLEC10 | c.1742C>T p.T581I | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV59487269; called by muse, mutect2, varscan2
- SIPA1L2 | c.3850G>A p.A1284T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV53401424; called by muse, mutect2, varscan2
- SIVA1 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV57331961; called by muse, mutect2, varscan2
- SKA3 | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs367718727; called by muse, mutect2, varscan2
- SLC12A2 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 215/539 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs768407146, COSV52469793, COSV52470791; called by muse, mutect2, varscan2
- SLC35A4 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV60054690; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC6A3 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs776553647, COSV54363722; called by muse, mutect2
- SLC6A4 | c.938T>C p.L313S | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55570177; called by muse, mutect2, varscan2
- SLC9A3 | c.782del p.G261Afs*15 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as COSV99375891; called by mutect2, pindel, varscan2
- SLC9C1 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV99997625; called by muse, mutect2
- SMARCA2 | c.4171A>G p.I1391V | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV56649456; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 121/387 reads (31%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SMG5 | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 134/660 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.45); catalogued as COSV62438255; called by muse, mutect2, varscan2
- SNX13 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 150/391 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs750665982, COSV68068652; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 134/403 reads (33%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX31 | c.542A>T p.D181V | Missense Mutation (SNP) | VAF 127/365 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV61265297; called by muse, mutect2, varscan2
- SPAM1 | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV56148544; called by muse, mutect2, varscan2
- SPECC1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54967526; called by muse, varscan2
- SPG21 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as COSV52604393; called by muse, mutect2, varscan2
- SPTBN1 | c.4189C>T p.H1397Y | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61695126; called by muse, mutect2, varscan2
- SPTLC3 | c.1447dup p.I483Nfs*39 | Frame Shift Ins (INS) | VAF 36/100 reads (36%) | catalogued as rs745509852; called by mutect2, varscan2
- SQLE | c.254del p.P85Lfs*25 | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | catalogued as rs760774524; called by mutect2, pindel, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 118/326 reads (36%) | catalogued as rs753297385; called by mutect2, varscan2
- ST3GAL6 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 88/243 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as COSV54585976; called by muse, mutect2, varscan2
- STAB1 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.417); catalogued as COSV100401450, COSV58739431; called by muse, mutect2
- STOX2 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV57857220; called by muse, mutect2, varscan2
- STRN3 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 172/415 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV62582249; called by muse, mutect2, varscan2
- SUGP2 | c.1727A>C p.D576A | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV58266312; called by muse, mutect2, varscan2
- SULT1C2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as COSV99265081; called by muse, mutect2
- SWT1 | c.1349T>A p.V450D | Missense Mutation (SNP) | VAF 107/491 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV62259732; called by muse, mutect2, varscan2
- TAF1D | c.281del p.K94Rfs*26 | Frame Shift Del (DEL) | VAF 111/302 reads (37%) | catalogued as rs746556335; called by mutect2, varscan2
- TANC1 | c.4068G>T p.E1356D | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55098669, COSV99713349; called by muse, mutect2, varscan2
- TAS2R3 | c.890T>C p.V297A | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56092955; called by muse, mutect2, varscan2
- TBC1D12 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 66/296 reads (22%) | catalogued as rs1356832965, COSV56558915; called by muse, mutect2, varscan2
- TCF20 | c.3200C>T p.T1067I | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV59496755; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | catalogued as rs748021112; called by mutect2, varscan2
- TCHH | c.4060C>T p.R1354C | Missense Mutation (SNP) | VAF 95/456 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs780658407, COSV64278195; called by muse, mutect2, varscan2
- TENM3 | c.4598C>T p.T1533I | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV69321396; called by muse, mutect2, varscan2
- TESPA1 | c.793C>T p.P265S (on ENST00000316577 / NM_001098815.3; = p.P127S on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57260517, COSV57261972; called by muse, mutect2, varscan2
- TLE1 | c.1326del p.K443Nfs*48 | Frame Shift Del (DEL) | VAF 38/225 reads (17%) | catalogued as COSV64689568; called by mutect2, pindel, varscan2
- TLR5 | c.1431G>T p.Q477H | Missense Mutation (SNP) | VAF 77/352 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV60561115; called by muse, mutect2, varscan2
- TLR7 | c.2956A>G p.I986V | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV66125739; called by muse, mutect2, varscan2
- TMEM26 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53264633; called by muse, mutect2, varscan2
- TNFRSF9 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as COSV66349773; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 67/192 reads (35%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TPD52L2 | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 22/64 reads (34%) | catalogued as rs771824613, COSV53864675; called by muse, mutect2, varscan2
- TRAK1 | c.2542A>G p.R848G | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV59648673; called by muse, mutect2, varscan2
- TRARG1 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1368006465, COSV100416809; called by muse, mutect2
- TRIM33 | c.2605C>T p.H869Y | Missense Mutation (SNP) | VAF 137/341 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV61823321; called by muse, mutect2, varscan2
- TRMT10C | c.393del p.K131Nfs*3 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs760928888; called by mutect2, varscan2
- TRMT112 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as COSV50008467; called by muse, mutect2, varscan2
- TRPM2 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV55978313; called by muse, mutect2, varscan2
- TSHR | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 35/578 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV99991447; called by muse, mutect2
- TSHZ1 | c.834G>T p.K278N (on ENST00000580243 / NM_001308210.2; = p.K233N on NM_005786.6) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV59018372; called by muse, mutect2, varscan2
- TSPAN14 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs544427528, COSV55420608; called by muse, mutect2, varscan2
- TSPAN32 | c.755T>C p.L252S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV51722378; called by muse, mutect2, varscan2
- TTC39B | c.1543T>C p.F515L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52608896; called by muse, mutect2, varscan2
- TXNL4B | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 152/393 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV51701342; called by muse, mutect2, varscan2
- UNC13B | c.1492C>T p.L498F | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV65939280; called by muse, mutect2, varscan2
- UNC79 | c.3928C>T p.R1310* (on ENST00000393151 / NM_001346218.2; = p.R1133* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 25/199 reads (13%) | catalogued as COSV56392694, COSV56415274; called by muse, mutect2, varscan2
- UROC1 | c.1997A>G p.D666G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV52040089; called by muse, mutect2, varscan2
- USP37 | c.2687G>A p.S896N | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV50299886; called by muse, mutect2, varscan2
- USP47 | c.417+2T>C p.X139_splice (on ENST00000399455 / NM_001372095.1; = p.X51_splice on NM_017944.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 39/133 reads (29%) | catalogued as COSV60468521; called by muse, mutect2, varscan2
- USP47 | c.3282del p.S1094Rfs*4 (on ENST00000399455 / NM_001372095.1; = p.S1006Rfs*4 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 125/386 reads (32%) | catalogued as COSV59693979, COSV59694818; called by mutect2, pindel, varscan2
- VGLL3 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs202199504, COSV67353621; called by muse, mutect2, varscan2
- VLDLR | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101173212; called by muse, mutect2, varscan2
- VWA3B | c.3760G>A p.A1254T | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.02); catalogued as COSV71368461; called by muse, mutect2, varscan2
- WBP4 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 202/591 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65274793; called by muse, mutect2, varscan2
- WDTC1 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV60090816; called by muse, varscan2
- WFIKKN1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV50195861; called by muse, mutect2
- XAB2 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99350182; called by muse, mutect2
- XRN2 | c.2842A>G p.N948D | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV101018167; called by muse, mutect2
- YAP1 | c.998T>A p.I333N | Missense Mutation (SNP) | VAF 196/507 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.319); catalogued as COSV56780176; called by muse, varscan2
- ZDHHC4 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 242/686 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV60107170; called by muse, mutect2, varscan2
- ZMYND8 | c.1714+2T>C p.X572_splice (on ENST00000311275 / NM_001363741.2; = p.X592_splice on NM_012408.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 72/194 reads (37%) | catalogued as COSV53697388; called by muse, mutect2, varscan2
- ZNF235 | c.951dup p.R318Tfs*6 | Frame Shift Ins (INS) | VAF 77/281 reads (27%) | catalogued as rs1568643094; called by mutect2, pindel, varscan2
- ZNF320 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1216418195, COSV67088010, COSV67088339; called by muse, mutect2, varscan2
- ZNF329 | c.782G>A p.C261Y | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63773589; called by muse, mutect2, varscan2
- ZNF426 | c.395T>C p.I132T | Missense Mutation (SNP) | VAF 135/345 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1360163354, COSV53470936; called by muse, mutect2, varscan2
- ZNF583 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV52404701, COSV52404927; called by muse, mutect2, varscan2
- ZNF589 | c.418dup p.A140Gfs*2 | Frame Shift Ins (INS) | VAF 20/85 reads (24%) | catalogued as rs764544661; called by mutect2, pindel, varscan2
- ZNF774 | c.910T>G p.S304A | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as rs1175875440, COSV62981242; called by muse, mutect2, varscan2
- ZNRF4 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs202092718, COSV99706438; called by muse, mutect2
- ZXDB | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 73/484 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV66493608; called by muse, mutect2, varscan2
- AAR2 | c.173_175del p.L58del | In Frame Del (DEL) | VAF 26/66 reads (39%) | called by pindel, varscan2
- ACSL5 | c.1266dup p.M423Hfs*19 (on ENST00000354273; = p.M479Hfs*19 on NM_016234.3) | Frame Shift Ins (INS) | VAF 75/239 reads (31%) | called by mutect2, pindel, varscan2
- ADAM9 | c.827del p.G276Vfs*28 | Frame Shift Del (DEL) | VAF 179/571 reads (31%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.292del p.R98Gfs*35 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- ALCAM | c.458del p.K153Sfs*34 | Frame Shift Del (DEL) | VAF 81/247 reads (33%) | called by mutect2, pindel, varscan2
- ARFGAP1 | c.883del p.S295Rfs*30 | Frame Shift Del (DEL) | VAF 36/122 reads (30%) | called by mutect2, pindel, varscan2
- ASH1L | c.3744_3745del p.H1248Qfs*5 | Frame Shift Del (DEL) | VAF 111/628 reads (18%) | called by mutect2, pindel, varscan2
- ASNSD1 | c.368_369del p.Y123Lfs*5 | Frame Shift Del (DEL) | VAF 107/386 reads (28%) | called by pindel, varscan2
- ATP9A | c.242del p.F81Sfs*17 | Frame Shift Del (DEL) | VAF 63/218 reads (29%) | called by mutect2, pindel, varscan2
- ATXN7L2 | c.563del p.P188Lfs*58 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | called by mutect2, pindel, varscan2
- BEX4 | c.122del p.G41Vfs*40 | Frame Shift Del (DEL) | VAF 35/104 reads (34%) | called by mutect2, pindel, varscan2
- BPTF | c.2614_2616del p.D872del | In Frame Del (DEL) | VAF 73/274 reads (27%) | called by mutect2, pindel, varscan2
- C12orf29 | c.265del p.R89Dfs*39 | Frame Shift Del (DEL) | VAF 55/186 reads (30%) | called by mutect2, pindel, varscan2
- CCNT2 | c.1300del p.M434Cfs*3 | Frame Shift Del (DEL) | VAF 55/154 reads (36%) | called by mutect2, pindel, varscan2
- CCR2 | c.472del p.V158Wfs*2 | Frame Shift Del (DEL) | VAF 148/468 reads (32%) | called by mutect2, pindel, varscan2
- COL19A1 | c.2027del p.P676Qfs*31 | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | called by mutect2, pindel, varscan2
- COL7A1 | c.949del p.E317Rfs*3 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- CUEDC1 | c.605del p.G202Afs*45 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- DMTN | c.281del p.P94Hfs*137 | Frame Shift Del (DEL) | VAF 72/214 reads (34%) | called by mutect2, pindel, varscan2
- DYTN | c.690_691del p.C231Qfs*19 | Frame Shift Del (DEL) | VAF 58/192 reads (30%) | called by pindel, varscan2
- EP300 | c.2944del p.M982Wfs*38 | Frame Shift Del (DEL) | VAF 61/230 reads (27%) | called by mutect2, pindel, varscan2
- ERLEC1 | c.505_507del p.E169del | In Frame Del (DEL) | VAF 108/312 reads (35%) | called by pindel, varscan2
- FUBP3 | c.705del p.D236Tfs*21 | Frame Shift Del (DEL) | VAF 121/422 reads (29%) | called by mutect2, pindel, varscan2
- HSPH1 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 28/192 reads (15%) | called by mutect2, varscan2
- KIFAP3 | c.607dup p.C203Lfs*16 | Frame Shift Ins (INS) | VAF 54/270 reads (20%) | called by mutect2, varscan2
- KIR2DL4 | c.1177G>T p.G393* (on ENST00000396284; = p.G319* on NM_001080770.2) | Nonsense Mutation (SNP) | VAF 124/318 reads (39%) | called by muse, mutect2, varscan2
- LRCH2 | c.92del p.G31Efs*47 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- MBD1 | c.801dup p.A268Cfs*8 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- MROH1 | c.4024A>G p.T1342A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, varscan2
- MTMR10 | c.2110del p.L704Wfs*41 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- MYH3 | c.249del p.K84Sfs*11 | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | called by mutect2, pindel, varscan2
- NOTCH4 | c.2125del p.Q709Sfs*22 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- OPLAH | c.2669del p.G890Afs*8 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- OR14C36 | c.844del p.L282Sfs*14 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel
- ORC4 | c.1225A>G p.T409A | Missense Mutation (SNP) | VAF 12/409 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2
- PDZD11 | c.405del p.E136Rfs*22 | Frame Shift Del (DEL) | VAF 81/237 reads (34%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1740_1745+3del p.X580_splice (on ENST00000521381 / NM_181523.3; = p.X310_splice on NM_181504.4) | Splice Site (DEL) | VAF 132/425 reads (31%) | called by mutect2, pindel, varscan2
- PNMA2 | c.260del p.G87Vfs*5 | Frame Shift Del (DEL) | VAF 65/201 reads (32%) | called by mutect2, pindel, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 71/225 reads (32%) | called by mutect2, pindel, varscan2
- PRKDC | c.12069dup p.G4024Rfs*12 | Frame Shift Ins (INS) | VAF 242/735 reads (33%) | called by mutect2, pindel, varscan2
- RAB38 | c.63dup p.K22Efs*78 | Frame Shift Ins (INS) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- RLF | c.5613_5614del p.C1871Wfs*18 | Frame Shift Del (DEL) | VAF 76/296 reads (26%) | called by pindel, varscan2
- S100A8 | c.256del p.S86Afs*10 | Frame Shift Del (DEL) | VAF 65/318 reads (20%) | called by mutect2, pindel, varscan2
- SEMA3B | c.1219del p.L407Sfs*52 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- SERPINA11 | c.781dup p.C261Lfs*20 | Frame Shift Ins (INS) | VAF 48/168 reads (29%) | called by mutect2, pindel, varscan2
- SF3B4 | c.1060del p.R354Efs*26 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- SHARPIN | c.986del p.P329Hfs*83 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.55del p.A19Hfs*34 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | called by mutect2, pindel, varscan2
- SLC17A8 | c.1631dup p.K545Efs*12 | Frame Shift Ins (INS) | VAF 59/185 reads (32%) | called by mutect2, pindel, varscan2
- SLC33A1 | c.788del p.F263Sfs*7 | Frame Shift Del (DEL) | VAF 66/210 reads (31%) | called by mutect2, varscan2
- SNAP29 | c.354del p.L119Wfs*10 | Frame Shift Del (DEL) | VAF 50/178 reads (28%) | called by mutect2, pindel, varscan2
- SRD5A2 | c.249dup p.L84Sfs*52 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- STIM2 | c.1609del p.H537Tfs*64 | Frame Shift Del (DEL) | VAF 41/132 reads (31%) | called by mutect2, pindel, varscan2
- SYCP2 | c.2548del p.S850Afs*5 | Frame Shift Del (DEL) | VAF 138/486 reads (28%) | called by mutect2, pindel, varscan2
- TENM3 | c.6418del p.T2140Qfs*8 | Frame Shift Del (DEL) | VAF 48/165 reads (29%) | called by mutect2, pindel, varscan2
- TLR1 | c.805dup p.W269Lfs*25 | Frame Shift Ins (INS) | VAF 83/275 reads (30%) | called by mutect2, pindel, varscan2
- TMEM268 | c.384dup p.N129Efs*25 | Frame Shift Ins (INS) | VAF 110/375 reads (29%) | called by mutect2, pindel, varscan2
- TPR | c.3621del p.E1208Kfs*24 | Frame Shift Del (DEL) | VAF 52/532 reads (10%) | called by mutect2, pindel
- TSPAN9 | c.484del p.E162Rfs*33 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- UBB | c.570del p.D191Tfs*35 | Frame Shift Del (DEL) | VAF 86/229 reads (38%) | called by mutect2, varscan2
- WASHC4 | c.3116del p.N1039Ifs*20 | Frame Shift Del (DEL) | VAF 92/264 reads (35%) | called by mutect2, varscan2
- ZBTB20 | c.1727del p.K576Sfs*42 (on ENST00000474710 / NM_001164342.2; = p.K503Sfs*42 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 43/128 reads (34%) | called by mutect2, pindel, varscan2
- ZMIZ2 | c.38del p.P13Lfs*60 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- ZMPSTE24 | c.977dup p.N326Kfs*2 | Frame Shift Ins (INS) | VAF 68/244 reads (28%) | called by mutect2, pindel, varscan2
- ZNF292 | c.7633dup p.R2545Kfs*4 | Frame Shift Ins (INS) | VAF 26/84 reads (31%) | called by mutect2, varscan2
- ZNF471 | c.696del p.K232Nfs*157 | Frame Shift Del (DEL) | VAF 49/146 reads (34%) | called by mutect2, pindel, varscan2
- ZNF532 | c.1260del p.R421Gfs*9 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- ABCB9 | c.1206C>T p.N402= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV54894606; called by muse, mutect2, varscan2
- AC004593.2 | c.1614C>T p.N538= | Silent (SNP) | VAF 64/208 reads (31%) | catalogued as rs765860302, COSV56102852; called by muse, mutect2, varscan2
- ACAN | c.2640T>C p.L880= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV61370710; called by muse, mutect2, varscan2
- ADGRG7 | c.34C>T p.L12= | Silent (SNP) | VAF 125/374 reads (33%) | catalogued as COSV56301902; called by muse, mutect2, varscan2
- ANGPTL2 | c.354C>T p.S118= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs774915769, COSV52234258; called by muse, mutect2, varscan2
- ANK1 | c.5118C>T p.D1706= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs372080096, COSV55892542; called by muse, mutect2, varscan2
- AP5B1 | c.1086G>A p.P362= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1226658701, COSV57504804; called by muse, mutect2, varscan2
- APAF1 | c.135T>C p.N45= | Silent (SNP) | VAF 75/196 reads (38%) | catalogued as COSV54491370; called by muse, mutect2, varscan2
- APC | c.5979T>C p.P1993= | Silent (SNP) | VAF 67/187 reads (36%) | catalogued as COSV99966595; called by muse, mutect2, varscan2
- ARID4B | c.2466T>C p.R822= | Silent (SNP) | VAF 187/941 reads (20%) | catalogued as COSV51612316; called by muse, mutect2, varscan2
- BEST3 | c.930C>T p.C310= | Silent (SNP) | VAF 201/527 reads (38%) | catalogued as COSV58306470; called by muse, mutect2, varscan2
- BRPF3 | c.2778C>T p.R926= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs899842134, COSV60205652; called by muse, mutect2, varscan2
- C4BPA | c.1299C>A p.A433= | Silent (SNP) | VAF 177/874 reads (20%) | catalogued as COSV65537886; called by muse, mutect2, varscan2
- CALR | c.792A>G p.P264= | Silent (SNP) | VAF 64/177 reads (36%) | catalogued as COSV57138532; called by muse, mutect2, varscan2
- CARMIL1 | c.2394C>T p.H798= | Silent (SNP) | VAF 124/320 reads (39%) | catalogued as rs754460838, COSV61524855; called by muse, mutect2, varscan2
- CCDC38 | c.1045C>T p.L349= | Silent (SNP) | VAF 170/457 reads (37%) | catalogued as COSV60182532; called by muse, mutect2, varscan2
- CCDC88A | c.2757A>G p.Q919= | Silent (SNP) | VAF 204/573 reads (36%) | catalogued as rs542447642, COSV55071002; called by muse, mutect2, varscan2
- CELSR1 | c.2415C>T p.G805= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV53101374; called by muse, mutect2, varscan2
- CES5A | c.1048C>T p.L350= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV51866194; called by muse, mutect2, varscan2
- CHRNA10 | c.249G>A p.R83= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV51707636; called by muse, mutect2, varscan2
- CLPB | c.669C>T p.S223= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV53634285; called by muse, mutect2, varscan2
- CPED1 | c.375G>A p.T125= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs141259188; called by muse, mutect2, varscan2
- CYSLTR2 | c.405G>A p.V135= | Silent (SNP) | VAF 157/390 reads (40%) | catalogued as COSV56167204; called by muse, mutect2, varscan2
- DBNL | c.258C>A p.G86= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs371897495; called by muse, mutect2, varscan2
- DRC3 | c.612G>A p.K204= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV58266959; called by muse, mutect2, varscan2
- DSE | c.549T>C p.N183= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV59067850; called by muse, mutect2, varscan2
- DUSP10 | c.894C>G p.G298= | Silent (SNP) | VAF 18/116 reads (16%) | called by muse, varscan2
- DYNC1H1 | c.5283C>T p.N1761= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs1057523440, COSV64143732; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF3B | c.555G>T p.S185= | Silent (SNP) | VAF 65/170 reads (38%) | catalogued as COSV62805349; called by muse, mutect2, varscan2
- FARSA | c.1065C>T p.R355= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs747899400, COSV58906220; called by muse, mutect2, varscan2
- FAT4 | c.4969A>C p.R1657= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV67902197; called by muse, mutect2, varscan2
- FGF12 | c.606T>C p.P202= (on ENST00000454309 / NM_021032.5; = p.P140= on NM_004113.6) | Silent (SNP) | VAF 130/341 reads (38%) | catalogued as COSV53191706; called by muse, mutect2, varscan2
- FGF13 | c.360G>A p.K120= | Silent (SNP) | VAF 108/237 reads (46%) | catalogued as COSV59550984; called by muse, mutect2, varscan2
- GBP2 | c.1305T>C p.T435= | Silent (SNP) | VAF 88/270 reads (33%) | catalogued as rs747729921, COSV65070658; called by muse, mutect2, varscan2
- GPRIN2 | c.1332G>A p.L444= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV65402887; called by muse, varscan2
- GUCY1B1 | c.1572C>T p.H524= | Silent (SNP) | VAF 65/200 reads (33%) | catalogued as COSV52379626; called by muse, mutect2, varscan2
- INPP4A | c.2814A>G p.R938= (on ENST00000074304 / NM_001134224.1; = p.R899= on NM_004027.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as COSV99303110; called by muse, mutect2
- INSR | c.3771A>G p.Q1257= | Silent (SNP) | VAF 81/234 reads (35%) | catalogued as COSV57174531; called by muse, mutect2, varscan2
- ITIH6 | c.1419G>A p.L473= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV54495657; called by muse, mutect2, varscan2
- ITPRID2 | c.2568G>A p.R856= | Silent (SNP) | VAF 62/175 reads (35%) | catalogued as COSV57477105; called by muse, mutect2, varscan2
- ITPRIP | c.813C>T p.H271= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs147462195; called by muse, mutect2, varscan2
- JAG1 | c.381C>T p.A127= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV54763677; called by muse, varscan2
- JMJD7-PLA2G4B | c.384G>A p.V128= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV59828975; called by muse, mutect2, varscan2
- KALRN | c.1059G>A p.Q353= | Silent (SNP) | VAF 91/236 reads (39%) | catalogued as rs1241492535, COSV53782220; called by muse, mutect2, varscan2
- KCTD18 | c.840C>T p.G280= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as rs188668776; called by muse, mutect2, varscan2
- KLHL12 | c.1536T>C p.Y512= | Silent (SNP) | VAF 95/450 reads (21%) | catalogued as rs140963884, COSV66128215; called by muse, mutect2, varscan2
- LAMC1 | c.2478C>T p.R826= | Silent (SNP) | VAF 97/373 reads (26%) | catalogued as rs201549183, COSV51185384; called by muse, mutect2, varscan2
- MAMDC4 | c.3096C>G p.P1032= (on ENST00000445819; = p.P953= on NM_206920.3) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV56377405, COSV99807921; called by mutect2, varscan2
- MAPT | c.1923C>T p.P641= (on ENST00000262410 / NM_001377265.1; = p.P249= on NM_005910.5) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52248690; called by muse, mutect2, varscan2
- MBNL2 | c.939C>T p.H313= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as COSV59126376; called by muse, mutect2, varscan2
- MCM6 | c.753G>A p.V251= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs1443928567, COSV51469914; called by muse, mutect2, varscan2
- MDN1 | c.12465G>A p.E4155= | Silent (SNP) | VAF 124/346 reads (36%) | catalogued as COSV65531615; called by muse, mutect2, varscan2
- MED12 | c.2202C>T p.Y734= | Silent (SNP) | VAF 55/148 reads (37%) | catalogued as rs1366328614, COSV61358288; called by muse, mutect2, varscan2
- MPDZ | c.5307A>G p.G1769= | Silent (SNP) | VAF 118/334 reads (35%) | catalogued as COSV59925584; called by muse, mutect2, varscan2
- NAP1L3 | c.1470T>C p.G490= | Silent (SNP) | VAF 122/318 reads (38%) | catalogued as COSV59077992; called by muse, mutect2, varscan2
- NAV2 | c.2430G>A p.Q810= (on ENST00000396087 / NM_001244963.2; = p.Q787= on NM_145117.5) | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV62337380; called by muse, mutect2, varscan2
- NF1 | c.5367A>G p.E1789= (on ENST00000358273 / NM_001042492.3; = p.E1768= on NM_000267.3) | Silent (SNP) | VAF 70/181 reads (39%) | catalogued as CD031870, COSV62224115; called by muse, mutect2, varscan2
- NHSL2 | c.1644A>G p.R548= (on ENST00000510661; = p.R914= on NM_001013627.2) | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as COSV65455246; called by muse, mutect2, varscan2
- NLRP8 | c.645A>G p.G215= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV52594899; called by muse, mutect2, varscan2
- NLRX1 | c.1440A>G p.P480= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV52710457; called by muse, mutect2, varscan2
- NUMB | c.1554C>A p.P518= (on ENST00000355058; = p.P507= on NM_003744.5) | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV53724978; called by muse, mutect2, varscan2
- OR56A1 | c.789G>A p.L263= | Silent (SNP) | VAF 57/140 reads (41%) | catalogued as COSV57364083; called by muse, mutect2, varscan2
- OR5M11 | c.405G>A p.T135= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as rs753561224, COSV73141683; called by muse, mutect2, varscan2
- OTUD7A | c.879C>T p.G293= (on ENST00000307050 / NM_001382637.1; = p.G286= on NM_130901.3) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs184361722, COSV61039967; called by muse, mutect2, varscan2
- PARD6B | c.441C>T p.D147= | Silent (SNP) | VAF 74/223 reads (33%) | catalogued as rs763295708, COSV65405393; called by muse, mutect2, varscan2
- PFKM | c.1311T>C p.H437= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs369182995; called by muse, mutect2, varscan2
- PI4KA | c.6240C>T p.S2080= | Silent (SNP) | VAF 56/189 reads (30%) | catalogued as COSV55425269; called by muse, mutect2, varscan2
- PIK3R2 | c.519C>T p.G173= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs750657176, COSV55850651; called by muse, mutect2, varscan2
- PLAT | c.1209C>T p.Y403= | Silent (SNP) | VAF 56/183 reads (31%) | catalogued as rs767986898, COSV54278585; called by muse, mutect2, varscan2
- PLEC | c.2661T>C p.S887= (on ENST00000322810 / NM_201380.4; = p.S777= on NM_000445.5) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV59702867; called by muse, mutect2, varscan2
- PLXND1 | c.2421C>T p.R807= | Silent (SNP) | VAF 90/265 reads (34%) | catalogued as COSV60720093; called by muse, mutect2, varscan2
- RBM18 | c.417C>T p.V139= | Silent (SNP) | VAF 10/338 reads (3%) | catalogued as COSV101313772; called by muse, mutect2
- RBM5 | c.1740C>T p.D580= | Silent (SNP) | VAF 58/158 reads (37%) | catalogued as rs771260903, COSV61739053; called by muse, mutect2, varscan2
- RGS11 | c.537G>A p.R179= (on ENST00000397770 / NM_183337.3; = p.R158= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV51454372; called by muse, mutect2, varscan2
- RITA1 | c.201C>T p.G67= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs752256248, COSV58376456; called by muse, mutect2, varscan2
- RNF148 | c.555G>A p.Q185= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as rs760362200, COSV57389056; called by muse, mutect2, varscan2
- RO60 | c.204C>T p.G68= | Silent (SNP) | VAF 40/198 reads (20%) | catalogued as COSV66475229; called by muse, mutect2, varscan2
- RPTN | c.885C>T p.Y295= | Silent (SNP) | VAF 268/1250 reads (21%) | catalogued as rs200576288, COSV60168525; called by muse, mutect2, varscan2
- SALL1 | c.1845C>A p.S615= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV51765302; called by muse, mutect2, varscan2
- SCAF8 | c.450T>C p.T150= | Silent (SNP) | VAF 9/187 reads (5%) | catalogued as COSV100914012; called by muse, mutect2
- SDCCAG8 | c.1194G>A p.T398= | Silent (SNP) | VAF 79/442 reads (18%) | catalogued as rs542036953, COSV59419014; called by muse, mutect2, varscan2
- SETD2 | c.1836T>C p.A612= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs1479622345, COSV57454032; called by muse, mutect2, varscan2
- SHC1 | c.1278C>A p.S426= (on ENST00000368445 / NM_183001.5; = p.S317= on NM_003029.5) | Silent (SNP) | VAF 38/191 reads (20%) | catalogued as COSV63535218; called by muse, mutect2, varscan2
- SIX3 | c.939C>T p.R313= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV53227909; called by muse, mutect2
- SLC12A2 | c.2661A>T p.G887= | Silent (SNP) | VAF 25/444 reads (6%) | catalogued as COSV99320849; called by muse, mutect2
- SLC4A7 | c.1443C>T p.Y481= | Silent (SNP) | VAF 12/322 reads (4%) | catalogued as COSV99839450; called by muse, mutect2
- SLC8B1 | c.9C>T p.G3= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs764503469, COSV52528374; called by muse, mutect2, varscan2
- SMAD2 | c.544C>A p.R182= | Silent (SNP) | VAF 106/274 reads (39%) | catalogued as rs370352616, COSV50993252; called by muse, mutect2, varscan2
- SNAPC4 | c.714C>T p.A238= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs754899181, COSV53738492; called by muse, mutect2, varscan2
- SPATA31A3 | c.3543G>A p.K1181= | Silent (SNP) | VAF 194/374 reads (52%) | called by mutect2, varscan2
- SPEN | c.1329C>T p.G443= | Silent (SNP) | VAF 120/417 reads (29%) | catalogued as COSV65368128; called by muse, mutect2, varscan2
- SPG11 | c.6213G>A p.K2071= | Silent (SNP) | VAF 116/309 reads (38%) | catalogued as COSV56003062; called by muse, mutect2, varscan2
- SYT15 | c.231C>T p.F77= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs371387345; called by muse, mutect2, varscan2
- TF | c.222C>T p.N74= | Silent (SNP) | VAF 58/144 reads (40%) | catalogued as rs200204609, COSV53924877; ClinVar: likely benign; called by muse, mutect2, varscan2
- TFAP2B | c.135G>A p.S45= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1260331751, COSV53832085; called by muse, mutect2, varscan2
- TLE4 | c.1605C>T p.Y535= | Silent (SNP) | VAF 72/177 reads (41%) | catalogued as rs1038243735, COSV54642557; called by muse, mutect2, varscan2
- TMEM40 | c.564G>T p.G188= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV53149059; called by muse, mutect2, varscan2
- TRIM35 | c.1254G>A p.S418= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs201064381; called by muse, mutect2, varscan2
- TRIML1 | c.246G>A p.R82= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV60197243; called by muse, mutect2, varscan2
- TTN | c.28302C>T p.G9434= (on ENST00000591111; = p.G8507= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/259 reads (39%) | catalogued as rs771825568, COSV60392012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGGT2 | c.1053A>T p.V351= | Silent (SNP) | VAF 10/293 reads (3%) | catalogued as COSV100943489; called by muse, mutect2
- USH2A | c.15282G>A p.P5094= | Silent (SNP) | VAF 80/420 reads (19%) | catalogued as rs754800723, COSV56360800, COSV56368419; called by muse, mutect2, varscan2
- USP22 | c.706C>A p.R236= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV54949346; called by muse, mutect2, varscan2
- VCAN | c.8244G>A p.Q2748= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV54118413; called by muse, mutect2, varscan2
- VCPKMT | c.408A>G p.P136= | Silent (SNP) | VAF 67/212 reads (32%) | catalogued as COSV53575684; called by muse, mutect2, varscan2
- VPS13B | c.2820T>C p.N940= | Silent (SNP) | VAF 66/198 reads (33%) | catalogued as COSV62142859; called by muse, varscan2
- VPS33B | c.1497C>T p.G499= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs767914174, COSV60981981; called by muse, mutect2, varscan2
- WDSUB1 | c.693T>C p.Y231= | Silent (SNP) | VAF 22/266 reads (8%) | catalogued as COSV100701796; called by muse, mutect2
- WNK1 | c.5763G>A p.V1921= (on ENST00000315939 / NM_018979.4; = p.V1673= on NM_014823.3) | Silent (SNP) | VAF 80/192 reads (42%) | catalogued as COSV60047286; called by muse, mutect2, varscan2
- WNK2 | c.3690G>A p.T1230= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as rs577808252, COSV52963466; called by muse, mutect2, varscan2
- WNT16 | c.207C>T p.S69= (on ENST00000222462 / NM_057168.2; = p.S59= on NM_016087.2) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV55977976; called by muse, mutect2, varscan2
- ZBTB40 | c.651T>G p.P217= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100988869; called by muse, mutect2
- ZNF236 | c.2361G>A p.Q787= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs1448711956, COSV53499374; called by muse, mutect2, varscan2
- ZNF597 | c.477T>C p.P159= | Silent (SNP) | VAF 150/421 reads (36%) | catalogued as COSV57085924; called by muse, mutect2, varscan2
- ZNF638 | c.705T>C p.T235= | Silent (SNP) | VAF 87/203 reads (43%) | catalogued as COSV52498209; called by muse, mutect2, varscan2
- ZSCAN29 | c.741C>T p.H247= | Silent (SNP) | VAF 102/261 reads (39%) | catalogued as COSV53021801; called by muse, mutect2, varscan2
- AFDN | chr6:167825783 G>A | 5'Flank (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1448-65T>C | Intron (SNP) | VAF 83/223 reads (37%) | called by muse, mutect2, varscan2
- C9orf163 | n.1450A>G | RNA (SNP) | VAF 13/66 reads (20%) | catalogued as rs1344365333; called by muse, mutect2, varscan2
- CCDC140 | n.667C>T | RNA (SNP) | VAF 8/29 reads (28%) | catalogued as rs1335346106, COSV54675663; called by muse, mutect2, varscan2
- COLQ | c.107-8889C>T | Intron (SNP) | VAF 22/71 reads (31%) | catalogued as rs370032148; called by muse, mutect2, varscan2
- CTBP2 | c.58+11513C>T | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as rs765891634, COSV58340483; called by muse, mutect2, varscan2
- GP6 | c.*157C>T | 3'UTR (SNP) | VAF 30/67 reads (45%) | catalogued as COSV59980035; called by muse, mutect2, varscan2
- MPIG6B | c.542-7del | Intron (DEL) | VAF 46/128 reads (36%) | catalogued as rs770605562; called by mutect2, pindel, varscan2
- MTMR11 | c.*225del | 3'UTR (DEL) | VAF 111/567 reads (20%) | catalogued as rs782186576; called by mutect2, pindel, varscan2
- NBPF11 | c.-549+2481G>A | Intron (SNP) | VAF 10/42 reads (24%) | catalogued as rs1558171720; called by muse, mutect2, varscan2
- POLA1 | c.2947-20857G>A | Intron (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948705 A>G | 3'Flank (SNP) | VAF 61/197 reads (31%) | catalogued as COSV57524676; called by muse, mutect2, varscan2
- RSRC2 | c.207+880del | Intron (DEL) | VAF 144/425 reads (34%) | called by mutect2, pindel, varscan2
- TRAC | c.*404del | 3'UTR (DEL) | VAF 54/175 reads (31%) | catalogued as rs754035003; called by mutect2, varscan2
- TRPM3 | c.979+16613G>A | Intron (SNP) | VAF 109/314 reads (35%) | catalogued as rs200079844, COSV62469962, COSV62471479; called by muse, mutect2, varscan2
